HCMI case HCM-EXPT-0977-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/f7947194-42ae-4c80-b539-3acf8ca5ca53

Demographics
Sex at birth: male; Year of birth: 1942.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.1; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Classification of tumor: primary; Age at diagnosis: 74.2 years (27,093 days); Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRINOX.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRINOX.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin Calcium; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRINOX.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRINOX.
   Recorded as not given: neoadjuvant Radiation Therapy, NOS.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-0977-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-0977-C25-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 1; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 99; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-0977-C25-01A-01-S1-HE: Section location: Top; Percent tumor cells: 12; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 87; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
